Somatic mutation profile of tumor specimen TCGA-24-1416-01A (aliquot TCGA-24-1416-01A-01W-0549-09) from TCGA case TCGA-24-1416, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: G3; Age at diagnosis: 35.0 years (12,772 days).
Specimen TCGA-24-1416-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) abc52c2a-fe27-4c8f-afc1-60c69c406888.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-24-1416-10A (Blood Derived Normal), aliquot TCGA-24-1416-10A-01W-0549-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d7a851d8-00d9-4a2a-b8f4-f014082fae50

The open-access MAF lists 21 somatic variants for this specimen: 15 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 12, Silent 6, Frame Shift Del 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 73/182 reads (40%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 106/128 reads (83%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADGRG7 | c.1715del p.L572* | Frame Shift Del (DEL) | VAF 134/386 reads (35%) | catalogued as COSV56301943; called by pindel, varscan2
- ALPL | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV66379960; called by muse, mutect2, varscan2
- CSPG5 | c.542G>A p.G181D | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.575); catalogued as rs768307634, COSV53134429; called by muse, varscan2
- HOXA7 | c.577G>A p.G193S | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs760210246, COSV99636198; called by muse, mutect2, varscan2
- OR5B21 | c.236C>T p.T79M | Missense Mutation (SNP) | VAF 122/257 reads (47%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.001); catalogued as rs777767732, COSV100835182, COSV64482359; called by muse, mutect2, varscan2
- PCDHA3 | c.190T>C p.F64L | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.157); catalogued as COSV65371919; called by muse, mutect2, varscan2
- RAD54L2 | c.3674G>T p.R1225L | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.061); catalogued as COSV56582229; called by muse, mutect2, varscan2
- RIMS2 | c.3106T>G p.S1036A (on ENST00000666250 / NM_001348490.2; = p.S844A on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 46/155 reads (30%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.058); catalogued as COSV51732766; called by muse, mutect2, varscan2
- SI | c.2809G>A p.E937K | Missense Mutation (SNP) | VAF 11/174 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.098); catalogued as COSV52299407; called by muse, mutect2
- TMC2 | c.1844G>A p.C615Y | Missense Mutation (SNP) | VAF 62/152 reads (41%) | SIFT tolerated (0.16); PolyPhen probably damaging (1); catalogued as COSV62659370; called by muse, mutect2, varscan2
- UGT2B11 | c.287G>C p.R96T | Missense Mutation (SNP) | VAF 170/913 reads (19%) | SIFT tolerated (0.7); PolyPhen benign (0.01); catalogued as COSV71424567; called by muse, mutect2, varscan2
- HSP90AA1 | c.730_733del p.E244Kfs*72 | Frame Shift Del (DEL) | VAF 28/75 reads (37%) | called by mutect2, pindel, varscan2
- RANBP17 | c.2585_2607del p.V862Afs*8 | Frame Shift Del (DEL) | VAF 121/322 reads (38%) | called by mutect2, pindel, varscan2
- ACTBL2 | c.882C>G p.L294= | Silent (SNP) | VAF 59/144 reads (41%) | catalogued as COSV70661929; called by muse, mutect2, varscan2
- CCNG2 | c.1002C>T p.F334= | Silent (SNP) | VAF 57/68 reads (84%) | catalogued as rs1304547016, COSV60353934, COSV60355005; called by muse, mutect2, varscan2
- CPS1 | c.1297C>T p.L433= | Silent (SNP) | VAF 85/196 reads (43%) | catalogued as COSV51827312; called by muse, mutect2, varscan2
- DCAF7 | c.825C>T p.A275= | Silent (SNP) | VAF 131/466 reads (28%) | catalogued as rs1314501149, COSV60409032; called by muse, mutect2, varscan2
- FATE1 | c.360A>C p.A120= | Silent (SNP) | VAF 210/453 reads (46%) | catalogued as COSV64849405; called by muse, mutect2, varscan2
- SEPSECS | c.999C>A p.G333= | Silent (SNP) | VAF 8/166 reads (5%) | catalogued as COSV100258619; called by muse, mutect2
